Somatic mutation profile of tumor specimen 0D9XFI from CCDI case PBBJJX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain stem; Age at diagnosis: 4.7 years (1,724 days).
Specimen 0D9XFI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) acf24207-8a5b-40ab-8738-0c0bc264ee32.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9XFL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b658ef69-ab24-48ed-8842-92f490028ea7

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPTA1 | c.7094C>T p.A2365V | Missense Mutation (SNP) | VAF 90/369 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as rs761063050, COSV63754540; called by muse, mutect2, varscan2
- WDFY4 | c.1888C>T p.R630W | Missense Mutation (SNP) | VAF 64/238 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs1462339605; called by muse, mutect2
- KCNJ4 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 34/372 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
